Somatic mutation profile of tumor specimen HCM-WCMC-0747-C50-01A (aliquot HCM-WCMC-0747-C50-01A-01D-A87L-36) from HCMI case HCM-WCMC-0747-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 43.2 years (15,793 days).
Specimen HCM-WCMC-0747-C50-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8da6ae9f-31e7-4d11-b36e-0d8205a872fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0747-C50-10A (Blood Derived Normal), aliquot HCM-WCMC-0747-C50-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98934cc5-b97e-427c-ab75-85b4440f6af4

The open-access MAF lists 3,267 somatic variants for this specimen: 2,417 protein-altering or splice-affecting, 713 silent, 137 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,058, Silent 713, Nonsense Mutation 296, Intron 82, Splice Site 26, 3'UTR 21, Splice Region 18, Frame Shift Ins 16, 5'Flank 14, 3'Flank 9, RNA 8, 5'UTR 3.

Variants (750 of 3,267; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3661C>T p.R1221C | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63751215, CM030401; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARG1 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 86/428 reads (20%) | catalogued as rs104893940, CM920106; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRCA1 | c.1793T>G p.L598* | Nonsense Mutation (SNP) | VAF 57/302 reads (19%) | catalogued as rs80357118, CM055907, CM117582; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.1137G>A p.T379= | Splice Region (SNP) | VAF 15/81 reads (19%) | catalogued as rs587783050, CS060517, COSV55733400; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNMT1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 47/247 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs751093624, COSV61576638; called by muse, mutect2, varscan2
- DOCK7 | c.3976C>T p.R1326* (on ENST00000635253 / NM_001367561.1; = p.R1295* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 60/347 reads (17%) | catalogued as rs756535975, COSV52000387; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1975A>G p.K659E | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519795, COSV60638890; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOXP1 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 43/245 reads (18%) | catalogued as rs1559602356, COSV59534092, COSV59536060; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ISCA1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.152); catalogued as rs776679653; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MERTK | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs878853354, CM148731, COSV54927455; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 74/359 reads (21%) | hotspot (GDC flag); catalogued as COSV54948051; called by muse, mutect2, varscan2
- MSH6 | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 49/247 reads (20%) | catalogued as rs1553333707, CM1412053, COSV52274101; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 54/391 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 70/364 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 47/221 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- SCN1A | c.4934G>A p.R1645Q (on ENST00000303395 / NM_001202435.3; = p.R1634Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121917976, CM072001, CM1511233, COSV57662283; ClinVar: pathogenic; called by muse, varscan2
- SPINK5 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 50/400 reads (13%) | catalogued as rs367958902, CM020795; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPTA1 | c.4975C>T p.R1659* | Nonsense Mutation (SNP) | VAF 40/249 reads (16%) | catalogued as rs1394141324, CM085728, COSV100935534; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 52/295 reads (18%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TMEM126A | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 83/367 reads (23%) | catalogued as rs121434508, CM092006, COSV58735100; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TUBA1A | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs886039513, CM145649, COSV55497204; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1BG | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 46/263 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.104); catalogued as COSV99568313; called by muse, mutect2, varscan2
- A2ML1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 51/295 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV55285440; called by muse, mutect2, varscan2
- A3GALT2 | c.35G>T p.R12I | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as rs1557808784; called by muse, mutect2, varscan2
- AADAC | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 50/259 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV99233421; called by muse, mutect2, varscan2
- AADACL4 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs778741834, COSV100879384; called by muse, mutect2, varscan2
- ABCA3 | c.1554C>A p.Y518* | Nonsense Mutation (SNP) | VAF 58/330 reads (18%) | catalogued as COSV57052448; called by muse, mutect2, varscan2
- ABCB6 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 76/327 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.54); catalogued as rs147046586; called by muse, mutect2, varscan2
- ABCG2 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs780975480, COSV52945734; called by muse, varscan2
- ABHD12B | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 55/249 reads (22%) | catalogued as rs909563542; called by muse, mutect2, varscan2
- ABHD16B | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53863610; called by muse, mutect2, varscan2
- AC004593.2 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 37/287 reads (13%) | PolyPhen benign (0); catalogued as rs1239091338; called by muse, mutect2, varscan2
- AC004922.1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as rs370232879; called by muse, mutect2, varscan2
- AC099489.1 | c.4237G>A p.A1413T | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs777140143; called by muse, mutect2, varscan2
- AC131160.1 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 27/280 reads (10%) | catalogued as COSV57700235; called by muse, mutect2
- AC231657.3 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as rs782678518; called by muse, mutect2, varscan2
- ACACB | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs753447548, COSV100623316; called by muse, mutect2, varscan2
- ACADM | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769906625, COSV63720304; called by muse, mutect2, varscan2
- ACAN | c.2944C>A p.L982I | Missense Mutation (SNP) | VAF 59/322 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.561); catalogued as rs1466854237; called by muse, mutect2, varscan2
- ACBD4 | c.659G>A p.R220H (on ENST00000376955 / NM_001378111.1; = p.P223= on NM_024722.4) | Missense Mutation (SNP) | VAF 62/374 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs557303418; called by muse, mutect2, varscan2
- ACBD6 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 48/398 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs777457819, COSV62571410, COSV62574403; called by muse, varscan2
- ACE | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52013980; called by muse, mutect2, varscan2
- ACIN1 | c.2282G>T p.R761I | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.184); catalogued as rs1240972538; called by muse, mutect2, varscan2
- ACSF2 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372494573; called by muse, mutect2, varscan2
- ACSM2B | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs576087006, COSV100313142; called by muse, mutect2, varscan2
- ACTN2 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV104426763, COSV63978633; called by muse, mutect2, varscan2
- ACTN2 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 50/421 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1270659015; called by muse, mutect2, varscan2
- ACTR1A | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV64024400; called by muse, mutect2, varscan2
- ACTR5 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs768469393; called by muse, mutect2, varscan2
- ACVR1 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 71/297 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55116621; called by muse, mutect2, varscan2
- ADAL | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1344077571; called by muse, mutect2, varscan2
- ADAM18 | c.1068T>G p.I356M | Missense Mutation (SNP) | VAF 46/292 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs201596679; called by muse, mutect2, varscan2
- ADAMTS1 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 47/360 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373807387; called by muse, mutect2, varscan2
- ADAMTS18 | c.3100C>T p.L1034F | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.195); catalogued as COSV51398434; called by muse, mutect2, varscan2
- ADAMTS18 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs775057284, COSV51408503; called by muse, mutect2, varscan2
- ADD3 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs767558945, COSV53321083; called by muse, mutect2, varscan2
- ADGRB3 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs779693752; called by muse, mutect2, varscan2
- ADGRE5 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs750288090, COSV99662851; called by muse, mutect2, varscan2
- ADGRF1 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV64800624; called by muse, mutect2, varscan2
- ADGRF5 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 38/246 reads (15%) | catalogued as COSV51937265; called by muse, mutect2, varscan2
- ADGRG4 | c.5974C>A p.L1992I | Missense Mutation (SNP) | VAF 88/410 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV54950689; called by muse, mutect2, varscan2
- ADGRG7 | c.786C>A p.F262L | Missense Mutation (SNP) | VAF 76/333 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751437270, COSV56301212, COSV99840688; called by muse, varscan2
- ADGRL2 | c.2518G>T p.D840Y (on ENST00000370717 / NM_001366005.1; = p.D827Y on NM_012302.4) | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs1189334334, COSV54677538; called by muse, mutect2, varscan2
- ADGRL3 | c.1667C>T p.S556L (on ENST00000506720 / NM_001322402.2; = p.S488L on NM_015236.6) | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs574618340, COSV72231044; called by muse, mutect2, varscan2
- ADGRL4 | c.25G>T p.V9F | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs547554975, COSV66064053; called by muse, mutect2, varscan2
- ADGRV1 | c.7007G>A p.R2336Q | Missense Mutation (SNP) | VAF 70/419 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs755180090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.7771G>A p.E2591K | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs757315634, COSV67978987; called by muse, mutect2, varscan2
- ADGRV1 | c.9481C>A p.P3161T | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67991519; called by muse, varscan2
- ADH5 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 27/282 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs773778500, COSV56447875, COSV99596150; called by muse, mutect2, varscan2
- ADNP2 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs756432927; called by muse, mutect2, varscan2
- AGAP2 | c.2564G>A p.R855H | Missense Mutation (SNP) | VAF 57/312 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs375555113; called by muse, mutect2, varscan2
- AGAP2 | c.2189G>A p.R730Q (on ENST00000547588 / NM_001122772.2; = p.R394Q on NM_014770.4) | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs867161743, COSV57731334; called by muse, mutect2, varscan2
- AGBL5 | c.80C>A p.S27Y | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV100549432; called by muse, mutect2, varscan2
- AGL | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 55/394 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.079); catalogued as rs776599112, CM140956, COSV54048187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGMO | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs1273447604, COSV61105744; called by muse, mutect2
- AGPAT3 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 98/267 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52367458; called by muse, mutect2, varscan2
- AGPS | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 65/304 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51560637, COSV51563645; called by muse, mutect2, varscan2
- AGTPBP1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 50/374 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as rs1387281487; called by muse, mutect2, varscan2
- AK2 | c.207C>T p.L69= (on ENST00000354858; = p.L111= on NM_001625.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 21/211 reads (10%) | catalogued as rs200433299; called by muse, mutect2, varscan2
- AKAP13 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV63453830; called by muse, mutect2, varscan2
- AKR7L | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs186763608; called by muse, mutect2, varscan2
- AKT1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1566818890, COSV62573359; called by muse, mutect2, varscan2
- ALS2 | c.3904C>T p.R1302C | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs759509511; called by muse, mutect2, varscan2
- AMDHD1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201031842; called by muse, mutect2, varscan2
- AMFR | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 71/279 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV51920352; called by muse, mutect2, varscan2
- ANGPTL7 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.068); catalogued as COSV63872036; called by mutect2, varscan2
- ANKEF1 | c.1487T>A p.I496N | Missense Mutation (SNP) | VAF 50/314 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs140725218; called by muse, mutect2, varscan2
- ANKRD26 | c.3058C>T p.R1020C | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.731); catalogued as rs761804757; called by muse, mutect2, varscan2
- ANKRD44 | c.2188C>T p.L730F | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.909); catalogued as rs767101123, COSV56553709; called by muse, mutect2, varscan2
- ANKRD62 | c.608T>G p.F203C | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.369); catalogued as COSV58409849; called by muse, mutect2, varscan2
- ANLN | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs772690246, COSV56075669; called by muse, varscan2
- ANLN | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 54/325 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs776619611; called by muse, mutect2, varscan2
- ANO5 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV100202188; called by muse, mutect2, varscan2
- ANO5 | c.2658G>T p.E886D | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100201294; called by muse, mutect2, varscan2
- ANO8 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 80/409 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251523199, COSV99344459; called by muse, mutect2, varscan2
- AOC2 | c.2118C>A p.F706L (on ENST00000253799 / NM_009590.4; = p.F679L on NM_001158.5) | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs772005140, COSV53824129, COSV53826096; called by muse, varscan2
- AP1AR | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 81/386 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as rs367798505; called by muse, mutect2, varscan2
- APBA1 | c.2190G>T p.K730N | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99595980, COSV99597291; called by mutect2, varscan2
- APOB | c.1931C>A p.S644Y | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs147173587, COSV51922803, COSV51933707; called by muse, mutect2, varscan2
- APOBEC1 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV57549020, COSV57550510; called by mutect2, varscan2
- APOBEC3F | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 24/199 reads (12%) | catalogued as rs773563808, COSV100415089; called by muse, mutect2, varscan2
- APOD | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 59/318 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs150503831; called by muse, mutect2
- AQP6 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as rs760593320; called by muse, mutect2, varscan2
- ARAP2 | c.4871G>A p.R1624Q | Missense Mutation (SNP) | VAF 58/307 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs1249697981, COSV58292022; called by muse, mutect2, varscan2
- ARHGAP11A | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 62/351 reads (18%) | catalogued as rs1487117985, COSV64381180; called by muse, mutect2, varscan2
- ARHGAP20 | c.3086C>A p.S1029Y | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV52811354, COSV52819056; called by mutect2, varscan2
- ARHGAP21 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs751405078, COSV57608900; called by muse, mutect2, varscan2
- ARHGAP5 | c.3352C>T p.R1118C | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs750575178, COSV61539117; called by muse, mutect2, varscan2
- ARHGEF10 | c.2012A>G p.D671G (on ENST00000398564; = p.D646G on NM_014629.4) | Missense Mutation (SNP) | VAF 55/340 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1446957268; called by muse, mutect2, varscan2
- ARHGEF12 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs34754222; called by muse, mutect2, varscan2
- ARHGEF17 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs1226836790; called by muse, mutect2, varscan2
- ARHGEF25 | c.1511G>T p.R504I | Missense Mutation (SNP) | VAF 65/249 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV99677913; called by muse, mutect2, varscan2
- ARHGEF3 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 63/289 reads (22%) | catalogued as COSV99575465; called by muse, mutect2, varscan2
- ARHGEF6 | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 44/343 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51687449; called by muse, mutect2, varscan2
- ARL1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1033216289, COSV55370222; called by muse, mutect2, varscan2
- ARL14 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV57899577; called by muse, varscan2
- ARNT | c.173A>C p.K58T | Missense Mutation (SNP) | VAF 37/427 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV104416818; called by muse, mutect2
- ARRDC3 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779678796; called by muse, mutect2, varscan2
- ARSK | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.324); catalogued as COSV66170448; called by muse, mutect2, varscan2
- ASAH1 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as rs1352441199; called by muse, mutect2, varscan2
- ASAH1 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.495); catalogued as COSV50501972, COSV50504395; called by muse, mutect2, varscan2
- ASAP1 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 69/350 reads (20%) | catalogued as COSV100727209; called by muse, mutect2, varscan2
- ASB15 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 54/288 reads (19%) | catalogued as COSV99306792; called by muse, mutect2, varscan2
- ASB2 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 65/382 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV60114246; called by muse, mutect2, varscan2
- ASH1L | c.4024C>T p.R1342* | Nonsense Mutation (SNP) | VAF 31/229 reads (14%) | catalogued as COSV64213851; called by muse, mutect2, varscan2
- ASNS | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV51552598; called by muse, mutect2, varscan2
- ASNS | c.593C>A p.S198Y | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.11); catalogued as COSV51554815, COSV99446307; called by muse, mutect2
- ASNSD1 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.365); catalogued as COSV53622915, COSV53623335; called by muse, mutect2, varscan2
- ASTN2 | c.2183C>T p.S728L (on ENST00000313400 / NM_001365069.1; = p.S677L on NM_014010.5) | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs144736118; called by muse, mutect2, varscan2
- ASXL3 | c.1032G>T p.K344N | Missense Mutation (SNP) | VAF 66/254 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52469766, COSV52480405; called by muse, mutect2, varscan2
- ASZ1 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV52912041; called by muse, mutect2, varscan2
- ATAD2 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV99783984; called by muse, mutect2, varscan2
- ATG12 | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.721); catalogued as rs561465491; called by muse, mutect2, varscan2
- ATG2B | c.3922C>T p.R1308C | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.963); catalogued as rs772425977, COSV55890367; called by muse, mutect2, varscan2
- ATP2A2 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 80/350 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs757914881, CM113597; called by muse, mutect2, varscan2
- ATP5PB | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 84/366 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs751833359, COSV52384704; called by muse, mutect2, varscan2
- ATP8A1 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 48/259 reads (19%) | catalogued as rs755553887, COSV100046625; called by muse, mutect2, varscan2
- ATP8B1 | c.3041G>A p.R1014Q | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.211); catalogued as rs756828618; called by muse, mutect2, varscan2
- ATP8B4 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 35/174 reads (20%) | catalogued as rs940798819, COSV52710402; called by muse, mutect2, varscan2
- ATP8B4 | c.1235G>T p.R412I | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as COSV52726883; called by mutect2, varscan2
- ATR | c.3898C>T p.R1300C | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779170933, COSV63386190; called by muse, mutect2
- ATR | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV63384749; called by muse, varscan2
- ATRX | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 60/386 reads (16%) | catalogued as COSV64873757, COSV64875914; called by muse, mutect2, varscan2
- ATXN2 | c.3632C>T p.T1211M (on ENST00000550104; = p.T1051M on NM_002973.4) | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1198968756, COSV57981626; called by muse, mutect2, varscan2
- AUTS2 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 65/301 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768770455, COSV61392212; called by muse, mutect2, varscan2
- AXL | c.1516C>T p.R506C (on ENST00000301178 / NM_021913.5; = p.R497C on NM_001699.6) | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456382289, COSV56566378; called by muse, mutect2, varscan2
- B2M | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 80/389 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs986783978; called by muse, mutect2, varscan2
- B2M | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 66/488 reads (14%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.573); catalogued as COSV62564083; called by muse, varscan2
- BACE1 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs371130142; called by muse, varscan2
- BACH1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 64/349 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750785692, COSV54518596; called by muse, mutect2, varscan2
- BARD1 | c.2221G>T p.D741Y | Missense Mutation (SNP) | VAF 69/318 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as rs587780029, COSV53616112; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BARX2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs376626609; called by muse, mutect2, varscan2
- BAZ1A | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62410075; called by muse, mutect2, varscan2
- BAZ2B | c.6416T>G p.F2139C | Missense Mutation (SNP) | VAF 70/389 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58603397; called by muse, mutect2, varscan2
- BECN1 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs775164058; called by muse, mutect2, varscan2
- BEND4 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV72468902; called by muse, mutect2, varscan2
- BEX1 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 60/365 reads (16%) | catalogued as COSV101022493; called by muse, mutect2, varscan2
- BEX1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 82/385 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as COSV65579974; called by muse, mutect2, varscan2
- BIRC3 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 46/363 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54815220; called by muse, mutect2, varscan2
- BIRC6 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70196110; called by muse, mutect2, varscan2
- BMP2 | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV66578028; called by muse, mutect2, varscan2
- BMP7 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 48/280 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV67780098; called by muse, mutect2, varscan2
- BMT2 | c.1032C>A p.F344L | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV51778386; called by muse, mutect2, varscan2
- BMX | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 53/336 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1323399158; called by muse, mutect2, varscan2
- BNIP5 | c.1695G>T p.R565S | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs779512450; called by mutect2, varscan2
- BRCA2 | c.3775A>C p.S1259R | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as rs587782071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD2 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 86/405 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66373510; called by muse, mutect2, varscan2
- BRF1 | c.1492C>T p.L498F | Missense Mutation (SNP) | VAF 73/331 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.808); catalogued as rs1260915920; called by muse, mutect2, varscan2
- BRINP2 | c.2104C>A p.L702I | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV64175866, COSV64180538; called by muse, mutect2, varscan2
- BRIP1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs375246789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.5237G>A p.R1746Q | Missense Mutation (SNP) | VAF 84/446 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.953); catalogued as rs918551619, COSV100956683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 51/344 reads (15%) | catalogued as COSV64748961, COSV64754484; called by muse, mutect2, varscan2
- BTK | c.1645G>T p.D549Y | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58123080; called by muse, mutect2, varscan2
- BTK | c.1044G>T p.E348D | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100437735; called by muse, mutect2, varscan2
- BTNL3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs778473610, COSV61564442; called by muse, mutect2, varscan2
- C11orf71 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 40/544 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); catalogued as COSV57784818; called by muse, mutect2
- C11orf86 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs779314012, COSV100457000, COSV58297178; called by muse, mutect2, varscan2
- C16orf89 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 74/335 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.325); catalogued as rs1366296763, COSV60125129; called by muse, varscan2
- C16orf96 | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 66/366 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs950903112; called by muse, mutect2
- C1QL4 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs750966716, COSV57743425; called by muse, mutect2, varscan2
- C1QTNF12 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 63/293 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs369520877; called by muse, mutect2, varscan2
- C1orf112 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 44/376 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs371455881; called by muse, mutect2, varscan2
- C1orf131 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); catalogued as COSV59642476; called by muse, mutect2
- C1orf87 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 50/334 reads (15%) | catalogued as rs147997086, COSV64596556; called by muse, mutect2, varscan2
- C20orf194 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 18/114 reads (16%) | catalogued as COSV99330190; called by mutect2, varscan2
- C2CD5 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 68/386 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61722731; called by muse, mutect2, varscan2
- C3orf38 | c.756A>C p.Q252H | Missense Mutation (SNP) | VAF 32/244 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759503705; called by muse, mutect2, varscan2
- C4orf46 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 75/325 reads (23%) | catalogued as rs749789362, COSV57014249; called by mutect2, varscan2
- C7orf31 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs531648664, COSV52216035; called by muse, mutect2, varscan2
- CA10 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); catalogued as rs139360662, COSV53343167; called by muse, mutect2, varscan2
- CAB39L | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs780505672, COSV61713671; called by muse, mutect2, varscan2
- CACNA1G | c.4159C>T p.R1387C | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61732758; called by muse, mutect2, varscan2
- CACNA2D3 | c.2253C>A p.F751L | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as COSV99875083, COSV99877863; called by muse, varscan2
- CACNB4 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs767538753, COSV52399686; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG6 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV53165592; called by muse, mutect2, varscan2
- CALCRL | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 64/420 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as COSV101131004; called by muse, mutect2, varscan2
- CALHM2 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 75/389 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as rs777338270; called by muse, varscan2
- CALML3 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 55/256 reads (21%) | catalogued as COSV100178790; called by muse, mutect2, varscan2
- CAMSAP2 | c.3964C>T p.R1322C (on ENST00000236925 / NM_001297707.2; = p.R1311C on NM_203459.3) | Missense Mutation (SNP) | VAF 62/415 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs140682641; called by muse, mutect2, varscan2
- CAPN2 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs1010016325, COSV54337515; called by muse, mutect2, varscan2
- CARMIL3 | c.2399C>T p.A800V | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as rs774345899, COSV57728187; called by muse, mutect2
- CASP8 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51846504, COSV99965286, COSV99965729; called by muse, mutect2, varscan2
- CCAR1 | c.3289T>G p.L1097V | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.987); catalogued as rs1040189895, COSV99771223; called by muse, mutect2, varscan2
- CCDC144A | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV60698178; called by muse, mutect2
- CCDC149 | c.1130C>T p.S377L (on ENST00000635206 / NM_001330643.2; = p.S366L on NM_173463.5) | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as rs373188183; called by muse, mutect2, varscan2
- CCDC168 | c.16274G>T p.R5425I | Missense Mutation (SNP) | VAF 70/363 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV104400445; called by muse, mutect2, varscan2
- CCDC174 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs201187132; called by muse, mutect2, varscan2
- CCDC54 | c.950T>G p.F317C | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs757621575, COSV99660123; called by muse, mutect2, varscan2
- CCDC88C | c.4703C>T p.S1568L | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as rs752668368, COSV57796258; called by muse, mutect2, varscan2
- CCKBR | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 90/362 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747382508, COSV58098347, COSV58103191; called by muse, mutect2, varscan2
- CCN2 | c.849C>A p.F283L | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63466512; called by muse, mutect2, varscan2
- CCPG1 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 72/350 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs753064740; called by muse, mutect2, varscan2
- CCSER1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs745548077, COSV100390706, COSV61437396; called by muse, mutect2, varscan2
- CCSER2 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs200068948, COSV56512306; called by muse, mutect2, varscan2
- CD101 | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 52/319 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200228819; called by muse, mutect2, varscan2
- CD209 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as rs774533179, COSV52653977; called by muse, mutect2, varscan2
- CD40LG | c.499G>T p.G167* | Nonsense Mutation (SNP) | VAF 52/388 reads (13%) | catalogued as CM054161, CM094863, CM146437, COSV65698374; called by muse, mutect2, varscan2
- CDC26 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs764264213, COSV65252464, COSV65252631; called by muse, mutect2, varscan2
- CDH23 | c.1450-1G>A p.X484_splice | Splice Site (SNP) | VAF 35/166 reads (21%) | catalogued as rs747981278; called by muse, mutect2, varscan2
- CDH5 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1342694698; called by muse, mutect2, varscan2
- CDH7 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); catalogued as COSV59886164; called by muse, mutect2, varscan2
- CDK17 | c.1029G>T p.K343N | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54130716; called by muse, mutect2, varscan2
- CDK19 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 63/312 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.34); catalogued as rs953895657; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1291G>T p.E431* (on ENST00000357886 / NM_001365728.1; = p.E417* on NM_016082.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 44/240 reads (18%) | catalogued as COSV59426587; called by muse, mutect2, varscan2
- CDK7 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 68/371 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56511769, COSV56515140; called by muse, mutect2, varscan2
- CDKL5 | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 69/327 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV66110977; called by muse, mutect2, varscan2
- CDKL5 | c.2177C>A p.S726Y | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as CX164601; called by mutect2, varscan2
- CEACAM8 | c.385C>A p.L129I | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.719); catalogued as COSV54991902; called by muse, varscan2
- CEL | c.642C>A p.F214L (on ENST00000673714; = p.F211L on NM_001807.6) | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV60827156; called by muse, mutect2, varscan2
- CENPE | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs866905901, COSV54378711; called by muse, mutect2, varscan2
- CENPF | c.5911T>C p.S1971P | Missense Mutation (SNP) | VAF 56/290 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV65274736; called by mutect2, varscan2
- CEP290 | c.3037G>T p.E1013* | Nonsense Mutation (SNP) | VAF 41/257 reads (16%) | catalogued as CM072942, COSV58350039; called by mutect2, varscan2
- CEP41 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1210916591; called by muse, mutect2, varscan2
- CERS3 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52565563; called by muse, mutect2, varscan2
- CERS4 | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 61/303 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1407588961; called by muse, mutect2, varscan2
- CETN2 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 54/248 reads (22%) | catalogued as COSV100938618; called by muse, mutect2, varscan2
- CFAP161 | c.371G>T p.R124I | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99715609; called by muse, mutect2, varscan2
- CFAP251 | c.3200G>A p.R1067Q | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1428337065, COSV56611369; called by muse, mutect2, varscan2
- CFAP45 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100928630; called by muse, mutect2, varscan2
- CFAP47 | c.4285C>T p.H1429Y | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV57974220; called by muse, mutect2
- CFAP57 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749165112; called by muse, mutect2, varscan2
- CFAP57 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV65263956, COSV65264322; called by muse, mutect2, varscan2
- CFAP91 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 52/297 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142545565; called by muse, mutect2, varscan2
- CFHR1 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57626879; called by muse, mutect2, varscan2
- CFHR4 | c.1040C>A p.S347Y (on ENST00000367416 / NM_001201551.2; = p.S101Y on NM_006684.5) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52231617; called by muse, mutect2, varscan2
- CHD2 | c.4711G>A p.D1571N | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.2); catalogued as rs780123418; called by muse, mutect2, varscan2
- CHD8 | c.1444C>T p.R482* (on ENST00000646647 / NM_001170629.2; = p.R203* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 68/308 reads (22%) | catalogued as COSV67870230; called by muse, mutect2, varscan2
- CHRM1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 81/354 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV61006177; called by muse, mutect2, varscan2
- CHRM3 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs749972605, COSV55079320; called by muse, mutect2, varscan2
- CHRM4 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 52/275 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.276); catalogued as rs780553103, COSV100708753; called by muse, mutect2, varscan2
- CHRNA9 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs139982841, CM1414136; called by muse, mutect2, varscan2
- CIP2A | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767069025, COSV55418459; called by muse, mutect2, varscan2
- CISD3 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 108/475 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1353251564; called by muse, mutect2, varscan2
- CKAP2 | c.305C>A p.P102H (on ENST00000378037 / NM_001098525.2; = p.P101H on NM_018204.5) | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51620833; called by muse, mutect2, varscan2
- CKM | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as rs200170574, COSV55532790; called by muse, mutect2, varscan2
- CLEC5A | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV69397018; called by muse, mutect2, varscan2
- CMKLR1 | c.995C>A p.S332Y (on ENST00000312143 / NM_001142344.2; = p.S330Y on NM_004072.3) | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV56436276; called by muse, mutect2, varscan2
- CNKSR3 | c.1578G>T p.K526N | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs1209760782; called by muse, mutect2, varscan2
- CNOT6L | c.455G>A p.R152Q (on ENST00000504123 / NM_001286790.2; = p.R147Q on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/417 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs781330689, COSV53699998; called by muse, mutect2, varscan2
- CNTNAP5 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 77/347 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757108906, COSV70486167; called by muse, mutect2, varscan2
- COL14A1 | c.3358C>T p.R1120* | Nonsense Mutation (SNP) | VAF 34/184 reads (18%) | catalogued as rs779378321, COSV52852069, COSV52861310; called by muse, mutect2, varscan2
- COL15A1 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 24/180 reads (13%) | catalogued as COSV100897626; called by mutect2, varscan2
- COL21A1 | c.863G>T p.R288I | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770639332, COSV55161169, COSV55161225; called by muse, varscan2
- COL24A1 | c.3982C>A p.L1328I | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV65304646, COSV65314258; called by muse, mutect2, varscan2
- COL6A5 | c.7504G>A p.D2502N (on ENST00000312481; = p.D2498N on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/338 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs752185068, COSV99593495; called by muse, mutect2, varscan2
- COL9A1 | c.1309G>T p.E437* | Nonsense Mutation (SNP) | VAF 68/339 reads (20%) | catalogued as COSV57879746; called by muse, mutect2, varscan2
- COLGALT2 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 39/176 reads (22%) | catalogued as rs373361853, COSV62298805; called by muse, mutect2, varscan2
- COPB1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 55/340 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369909236; called by muse, varscan2
- COQ8A | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 99/564 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143816043; called by muse, mutect2, varscan2
- CPA1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs148329227, COSV50575831; called by muse, mutect2, varscan2
- CPNE5 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs755076731, COSV55198199; called by muse, mutect2, varscan2
- CPS1 | c.3782C>T p.S1261F | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99241273; called by muse, mutect2, varscan2
- CRB2 | c.3274G>A p.E1092K | Missense Mutation (SNP) | VAF 92/349 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs542637649; called by muse, mutect2, varscan2
- CRIM1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); catalogued as rs372989532; called by muse, mutect2, varscan2
- CRNN | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 69/388 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs184532873; called by muse, mutect2
- CRYBG2 | c.4213G>A p.E1405K | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1203773831, COSV57485573; called by muse, mutect2, varscan2
- CRYBG3 | c.3117G>T p.K1039N | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs545501003; called by mutect2, varscan2
- CRYGD | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs753205493, COSV52204750; called by muse, mutect2, varscan2
- CSMD1 | c.4317C>A p.F1439L (on ENST00000520002; = p.F1438L on NM_033225.6) | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); catalogued as COSV59298436; called by muse, mutect2, varscan2
- CSMD3 | c.2032G>A p.D678N (on ENST00000297405 / NM_001363185.1; = p.D574N on NM_052900.3) | Missense Mutation (SNP) | VAF 89/429 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.418); catalogued as rs142207091, COSV99838134; called by muse, mutect2, varscan2
- CSNK1D | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs774858511, COSV53925579; called by muse, mutect2, varscan2
- CSNK1G3 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.166); catalogued as rs143075842; called by muse, varscan2
- CTNNA2 | c.2258C>A p.S753Y | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58153166; called by muse, mutect2, varscan2
- CTNNA3 | c.602G>T p.R201I | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV101050707; called by muse, mutect2, varscan2
- CTSC | c.1172C>T p.T391I | Missense Mutation (SNP) | VAF 75/340 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1324949386; called by muse, mutect2, varscan2
- CTSS | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV100935041, COSV64566055, COSV64567163; called by muse, mutect2, varscan2
- CUL2 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs749443608, COSV66078880; called by muse, mutect2, varscan2
- CUL9 | c.4977C>A p.F1659L | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52725227; called by muse, mutect2, varscan2
- CYB561D1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 57/312 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs1234971236, COSV100149777; called by muse, mutect2, varscan2
- CYP17A1 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as COSV64004932; called by muse, mutect2, varscan2
- CYP2A6 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs773401076; called by muse, mutect2, varscan2
- CYP2U1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 126/465 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV60549626; called by muse, mutect2, varscan2
- CYP3A4 | c.383G>T p.R128I | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60504759; called by muse, mutect2, varscan2
- CYSLTR1 | c.279C>A p.D93E | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs919220001; called by mutect2, varscan2
- DACT1 | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 70/374 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60023876; called by muse, mutect2, varscan2
- DAO | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201583577; called by muse, mutect2, varscan2
- DAPK1 | c.370C>A p.L124I | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63791889; called by muse, mutect2, varscan2
- DBF4B | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as rs774436262, COSV59258932, COSV59261867; called by muse, mutect2, varscan2
- DCAF6 | c.2242C>T p.R748W (on ENST00000312263 / NM_001349778.1; = p.R768W on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/477 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs745724831; called by muse, mutect2, varscan2
- DCLK2 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 57/282 reads (20%) | catalogued as COSV56200287; called by muse, mutect2, varscan2
- DCLRE1A | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 88/344 reads (26%) | catalogued as rs1212761218, COSV100800363; called by muse, mutect2, varscan2
- DCLRE1C | c.427G>T p.E143* (on ENST00000378278 / NM_001350965.2; = p.E28* on NM_022487.4) | Nonsense Mutation (SNP) | VAF 44/256 reads (17%) | catalogued as COSV100739877; called by muse, mutect2, varscan2
- DCP1B | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99767399; called by muse, mutect2, varscan2
- DCTN3 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.063); catalogued as rs765619518; called by muse, mutect2, varscan2
- DCXR | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs752090622; called by muse, mutect2, varscan2
- DDX10 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 41/313 reads (13%) | catalogued as COSV100489936; called by muse, mutect2, varscan2
- DDX17 | c.1819G>T p.E607* | Nonsense Mutation (SNP) | VAF 55/282 reads (20%) | catalogued as COSV53247135, COSV53249825; called by muse, mutect2, varscan2
- DEDD | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 41/330 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs754848698, COSV63502143; called by muse, mutect2, varscan2
- DENND2D | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs557909053; called by muse, mutect2, varscan2
- DGKD | c.3301G>A p.E1101K (on ENST00000264057 / NM_152879.3; = p.E1057K on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.107); catalogued as rs991285626; called by muse, mutect2, varscan2
- DHRS7C | c.449C>T p.A150V (on ENST00000330255 / NM_001220493.2; = p.A149V on NM_001105571.3) | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs773513074; called by muse, mutect2, varscan2
- DHX15 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61025483, COSV61029506; called by muse, mutect2, varscan2
- DHX40 | c.1913G>T p.R638I | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV99232976; called by muse, mutect2, varscan2
- DIPK2B | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs371509825; called by muse, mutect2, varscan2
- DLC1 | c.2338G>A p.D780N (on ENST00000276297 / NM_001348081.2; = p.D343N on NM_006094.5) | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV52300754; called by muse, varscan2
- DLX5 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 73/389 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56032639; called by muse, mutect2, varscan2
- DMRT2 | c.1308C>A p.F436L | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV52401652; called by muse, mutect2, varscan2
- DMXL2 | c.278G>T p.R93I | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as COSV99195926; called by muse, mutect2, varscan2
- DNAH10 | c.3624G>T p.E1208D (on ENST00000409039; = p.E1147D on NM_207437.3) | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.211); catalogued as COSV68991948; called by muse, varscan2
- DNAH11 | c.4669C>T p.R1557* | Nonsense Mutation (SNP) | VAF 46/287 reads (16%) | catalogued as rs759040005, COSV60977824; called by muse, mutect2, varscan2
- DNAH17 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs768308901, COSV101102013, COSV67758449; called by muse, mutect2, varscan2
- DNAH3 | c.8904G>T p.E2968D | Missense Mutation (SNP) | VAF 60/291 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104372710; called by muse, mutect2, varscan2
- DNAH5 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 57/283 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.063); catalogued as rs769557353, COSV99443519; called by muse, mutect2, varscan2
- DNAH6 | c.8677C>T p.R2893* | Nonsense Mutation (SNP) | VAF 73/355 reads (21%) | catalogued as rs552500475, COSV52850352; called by muse, mutect2, varscan2
- DNAH7 | c.6223C>A p.L2075I | Missense Mutation (SNP) | VAF 68/375 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.612); catalogued as rs1338784675, COSV56781678; called by muse, mutect2, varscan2
- DNAI4 | c.1870C>T p.R624* | Nonsense Mutation (SNP) | VAF 51/277 reads (18%) | catalogued as rs758550177, COSV64022904; called by muse, mutect2, varscan2
- DNAJA1 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 59/320 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs141132012; called by muse, mutect2, varscan2
- DNAJB1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs765857048; called by muse, mutect2, varscan2
- DNAJC13 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 80/371 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs547360849, COSV53446557; called by muse, mutect2, varscan2
- DNAJC9 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.563); catalogued as COSV54352541; called by muse, mutect2, varscan2
- DNAL1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as COSV60727344; called by muse, mutect2, varscan2
- DNASE1L1 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs782142885; called by muse, mutect2, varscan2
- DNM3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 67/499 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs527384140, COSV62455336; called by muse, mutect2, varscan2
- DNMBP | c.3254G>A p.R1085H | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs759738167, COSV60624289; called by muse, mutect2, varscan2
- DOCK11 | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 83/381 reads (22%) | catalogued as COSV99354069; called by muse, mutect2, varscan2
- DOCK2 | c.2513C>A p.S838Y | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56975150; called by muse, mutect2, varscan2
- DOCK6 | c.4738G>A p.D1580N | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762402181; called by muse, mutect2, varscan2
- DPAGT1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866685069; called by muse, mutect2
- DPPA3 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV61502790; called by muse, mutect2, varscan2
- DRC7 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs373094122; called by muse, mutect2, varscan2
- DSCC1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as rs144655317; called by muse, mutect2, varscan2
- DSEL | c.3098C>T p.S1033L | Missense Mutation (SNP) | VAF 93/430 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100025957, COSV59494476; called by muse, mutect2, varscan2
- DSG1 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767678194, COSV57133741; called by muse, mutect2, varscan2
- DST | c.14290G>T p.A4764S (on ENST00000361203 / NM_001374722.1; = p.A2352S on NM_015548.5) | Missense Mutation (SNP) | VAF 66/387 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.237); catalogued as rs763744714; called by mutect2, varscan2
- DST | c.2489G>A p.R830Q (on ENST00000361203 / NM_001374722.1; = p.R504Q on NM_001723.6) | Missense Mutation (SNP) | VAF 66/373 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762435098; called by muse, mutect2, varscan2
- DYNC1I2 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 50/369 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs1294804898, COSV55525775; called by muse, varscan2
- DYNC1I2 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV99784225; called by muse, mutect2, varscan2
- DYNC2H1 | c.6044G>A p.R2015Q | Missense Mutation (SNP) | VAF 85/338 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs775984088, COSV62091815; called by muse, varscan2
- DYRK1A | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs556482236, COSV100117324; called by muse, mutect2, varscan2
- EBF2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 45/283 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68776583, COSV68780548; called by muse, varscan2
- ECE1 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 48/325 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.351); catalogued as rs754109847, COSV51662852; called by muse, mutect2, varscan2
- ECE1 | c.1620C>A p.F540L | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV99941319; called by muse, mutect2, varscan2
- ECH1 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 49/323 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.271); catalogued as rs1403167483; called by muse, mutect2, varscan2
- ECT2 | c.2392G>A p.A798T (on ENST00000392692 / NM_001349098.2; = p.A767T on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as rs752178167; called by muse, mutect2, varscan2
- ECT2L | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs754540928, COSV62882962; called by muse, mutect2, varscan2
- EEA1 | c.999G>T p.K333N | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV59287992; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 52/267 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs748024573, COSV66964361; called by muse, mutect2, varscan2
- EFCAB3 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV59501014; called by muse, mutect2, varscan2
- EFHC1 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 99/435 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs766799700; called by muse, mutect2, varscan2
- EFR3A | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs1291653738, COSV54459529; called by muse, mutect2, varscan2
- EFR3B | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 70/299 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101241465; called by muse, mutect2, varscan2
- EGFR | c.3202C>T p.R1068* | Nonsense Mutation (SNP) | VAF 52/286 reads (18%) | catalogued as rs749783044, COSV51803089; called by muse, varscan2
- EGR2 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 85/402 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54347773; called by muse, mutect2, varscan2
- EHBP1 | c.3593C>T p.A1198V | Missense Mutation (SNP) | VAF 70/300 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99859721; called by muse, mutect2, varscan2
- EHD3 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV59030349; called by muse, mutect2, varscan2
- EHF | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757126229, COSV57669499; called by muse, mutect2, varscan2
- ELOA | c.1807C>A p.L603I | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99072567; called by muse, mutect2, varscan2
- ELOVL1 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201270403; called by muse, mutect2, varscan2
- EMC2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs1030080319; called by muse, mutect2, varscan2
- EMILIN2 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV54422529, COSV54425336; called by muse, mutect2
- EML3 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 111/439 reads (25%) | catalogued as COSV53882422; called by muse, mutect2, varscan2
- ENDOD1 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773730577; called by muse, mutect2, varscan2
- ENO1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs371689591; called by muse, mutect2, varscan2
- ENO2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs782101405; called by muse, mutect2, varscan2
- ENOX2 | c.1108C>T p.R370C (on ENST00000338144 / NM_001382520.1; = p.R341C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs199818795, COSV57650385; called by muse, mutect2, varscan2
- ENPEP | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 96/404 reads (24%) | catalogued as rs143343563, COSV54448047; called by muse, mutect2, varscan2
- ENPEP | c.2672G>A p.R891Q | Missense Mutation (SNP) | VAF 74/309 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770598233, COSV54448376; called by muse, mutect2, varscan2
- EOLA2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 84/560 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.055); catalogued as rs144047890; called by muse, mutect2, varscan2
- EP400 | c.2635G>T p.E879* | Nonsense Mutation (SNP) | VAF 20/253 reads (8%) | catalogued as COSV57762391, COSV57787435; called by muse, mutect2
- EP400 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.654); catalogued as rs766432250, COSV57780225; called by muse, mutect2, varscan2
- EPB41L5 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1414991675, COSV55354222; called by muse, mutect2, varscan2
- EPHA7 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 64/382 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV100993288; called by muse, mutect2, varscan2
- EPHB2 | c.1792G>A p.D598N (on ENST00000400191 / NM_001309193.2; = p.D599N on NM_004442.7) | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368925967, COSV65866147; called by muse, mutect2, varscan2
- EPS15 | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs762929521; called by muse, mutect2, varscan2
- EPS15 | c.1816A>C p.S606R | Missense Mutation (SNP) | VAF 62/311 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV65540465; called by muse, mutect2, varscan2
- EPS8 | c.1711C>T p.R571* | Nonsense Mutation (SNP) | VAF 38/265 reads (14%) | catalogued as rs1457535054, COSV55528972; called by muse, mutect2, varscan2
- EPS8L2 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.684); catalogued as COSV100585472; called by muse, mutect2
- ERCC6 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs768589918, COSV63388430; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERICH5 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 35/207 reads (17%) | catalogued as COSV59315405; called by muse, mutect2, varscan2
- ESF1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 79/327 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs186231642, COSV52518687, COSV52523168; called by muse, mutect2, varscan2
- ESYT3 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.342); catalogued as rs769328420, COSV56679687; called by muse, mutect2, varscan2
- ETV3 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs1163203810, COSV58748797; called by muse, mutect2, varscan2
- ETV4 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 65/329 reads (20%) | catalogued as COSV52252013; called by muse, mutect2, varscan2
- EVL | c.992C>T p.S331L (on ENST00000402714 / NM_001330221.2; = p.S333L on NM_016337.3) | Missense Mutation (SNP) | VAF 59/333 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV67375968; called by muse, mutect2, varscan2
- EXOC2 | c.2512C>T p.R838* | Nonsense Mutation (SNP) | VAF 59/312 reads (19%) | catalogued as rs1054082684; called by muse, mutect2, varscan2
- EXOC8 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 52/318 reads (16%) | catalogued as COSV50478059; called by muse, mutect2, varscan2
- EXTL2 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 52/271 reads (19%) | catalogued as COSV64472964; called by muse, varscan2
- EYA4 | c.1240C>T p.R414C (on ENST00000531901 / NM_001301013.1; = p.R408C on NM_004100.5) | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs775741050, COSV62045783, COSV62051715; called by muse, mutect2, varscan2
- EZHIP | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 89/421 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV100539606; called by muse, mutect2, varscan2
- F5 | c.3409C>A p.Q1137K | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as CM105383; called by muse, mutect2, varscan2
- F8 | c.3407C>T p.S1136F | Missense Mutation (SNP) | VAF 75/336 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.483); catalogued as COSV64273005, COSV64273639; called by muse, mutect2, varscan2
- F9 | c.89-1G>T p.X30_splice | Splice Site (SNP) | VAF 57/229 reads (25%) | catalogued as CS930794, CS941473, CS961561, CX962377; called by muse, mutect2, varscan2
- FAAH2 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs201590323; called by muse, mutect2, varscan2
- FAAH2 | c.1166G>T p.S389I | Missense Mutation (SNP) | VAF 70/422 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.492); catalogued as rs752160314; called by mutect2, varscan2
- FAM102B | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 56/397 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs771513451; called by muse, mutect2, varscan2
- FAM107B | c.278C>G p.S93* | Nonsense Mutation (SNP) | VAF 91/367 reads (25%) | catalogued as rs778239622, COSV99473424, COSV99474364; called by muse, mutect2, varscan2
- FAM126B | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 53/386 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.273); catalogued as rs772869036; called by muse, mutect2, varscan2
- FAM135A | c.1760C>A p.S587Y | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV99525747; called by muse, mutect2, varscan2
- FAM13A | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 33/226 reads (15%) | catalogued as rs747994413, COSV99983290; called by muse, mutect2, varscan2
- FAM186A | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 43/235 reads (18%) | catalogued as rs541010309, COSV59256231; called by muse, varscan2
- FAM189A2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs764688447; called by muse, mutect2, varscan2
- FAM210B | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 84/345 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs17851557; called by muse, mutect2, varscan2
- FAM237A | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as COSV101405598, COSV69304999; called by muse, mutect2, varscan2
- FAM47C | c.2088G>T p.E696D | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.635); catalogued as rs1328446187; called by muse, mutect2, varscan2
- FAM83A | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 39/309 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs548147359; called by muse, mutect2, varscan2
- FAM83G | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs376887547; called by muse, mutect2, varscan2
- FANCB | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as rs1057515811, COSV60759570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAR2 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as rs1475516172; called by muse, varscan2
- FAR2 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767224864; called by muse, varscan2
- FAT1 | c.10672G>A p.E3558K | Missense Mutation (SNP) | VAF 48/325 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV101499017; called by muse, mutect2, varscan2
- FAT1 | c.2979G>T p.K993N | Missense Mutation (SNP) | VAF 75/340 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as rs1397804525, COSV104437747, COSV71673670; called by muse, mutect2, varscan2
- FAT2 | c.2592G>T p.E864D | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55822333; called by muse, mutect2, varscan2
- FAT3 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.806); catalogued as rs780987790, COSV53079281; called by muse, mutect2, varscan2
- FAT3 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 46/249 reads (18%) | catalogued as COSV53072200, COSV53124569, COSV99963822; called by muse, mutect2, varscan2
- FAT4 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 77/426 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1165902550, COSV67882453; called by muse, mutect2, varscan2
- FAT4 | c.3041G>A p.R1014Q | Missense Mutation (SNP) | VAF 63/330 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.522); catalogued as rs377288957; called by muse, mutect2, varscan2
- FBN1 | c.1035C>A p.C345* | Nonsense Mutation (SNP) | VAF 43/238 reads (18%) | catalogued as CM098623; called by muse, mutect2, varscan2
- FBN3 | c.5428C>T p.R1810W | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as rs902177398; called by muse, mutect2, varscan2
- FBXL2 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.051); catalogued as rs986759962; called by muse, mutect2, varscan2
- FBXL3 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 60/383 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs560551710, COSV62918460; called by muse, mutect2, varscan2
- FBXW10 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1298042791; called by muse, mutect2, varscan2
- FBXW2 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs761775371; called by muse, mutect2, varscan2
- FCHSD2 | c.333C>A p.F111L | Missense Mutation (SNP) | VAF 72/313 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60812008; called by muse, mutect2, varscan2
- FER1L6 | c.198-1G>T p.X66_splice | Splice Site (SNP) | VAF 42/223 reads (19%) | catalogued as COSV101205590, COSV67552110; called by muse, mutect2, varscan2
- FER1L6 | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs191271444; called by muse, mutect2, varscan2
- FGA | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs763555716, COSV57393105; called by muse, mutect2, varscan2
- FGF19 | c.564C>A p.F188L | Missense Mutation (SNP) | VAF 48/284 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.113); catalogued as COSV53736124; called by muse, mutect2, varscan2
- FGFRL1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 88/413 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.33); catalogued as rs763867368, COSV53259370; called by muse, mutect2, varscan2
- FGL2 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.689); catalogued as rs1459657752, COSV50381411; called by muse, mutect2, varscan2
- FILIP1 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.343); catalogued as rs868698674, COSV52728473; called by muse, mutect2, varscan2
- FLG | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs748903619, COSV100910357; called by muse, mutect2, varscan2
- FLII | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs201233040, COSV57497649; called by muse, mutect2, varscan2
- FLT4 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 100/422 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs752512978, COSV56105948; called by muse, mutect2, varscan2
- FMN2 | c.4195C>A p.L1399I | Missense Mutation (SNP) | VAF 53/382 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV60422366; called by muse, mutect2, varscan2
- FNDC7 | c.1997G>A p.G666D | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763013847; called by muse, mutect2, varscan2
- FOXD4L1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 80/409 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.374); catalogued as rs755139743, COSV52075704; called by muse, mutect2, varscan2
- FOXJ3 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 75/355 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as rs377432876; called by muse, mutect2, varscan2
- FOXO1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1034299550, COSV65425761; called by muse, varscan2
- FOXP3 | c.551C>A p.S184* | Nonsense Mutation (SNP) | VAF 45/278 reads (16%) | catalogued as COSV66051439; called by muse, mutect2, varscan2
- FREM2 | c.3092C>A p.S1031Y | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.205); catalogued as COSV54830140; called by mutect2, varscan2
- FRMD7 | c.2005G>T p.E669* | Nonsense Mutation (SNP) | VAF 63/354 reads (18%) | catalogued as COSV100048847, COSV100048949; called by muse, mutect2, varscan2
- FRY | c.922G>T p.D308Y | Missense Mutation (SNP) | VAF 76/431 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66567638; called by muse, mutect2, varscan2
- FRYL | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 53/283 reads (19%) | catalogued as COSV51962506; called by muse, mutect2, varscan2
- FSIP1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 30/289 reads (10%) | catalogued as COSV100618116; called by muse, mutect2, varscan2
- FSIP2 | c.15121C>A p.Q5041K | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV58077376; called by muse, mutect2
- FSIP2 | c.16948C>T p.R5650* | Nonsense Mutation (SNP) | VAF 40/262 reads (15%) | catalogued as rs746547008, COSV100555848, COSV58087277; called by muse, mutect2, varscan2
- FSTL3 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as rs978479865; called by muse, mutect2, varscan2
- FUCA2 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 39/206 reads (19%) | catalogued as COSV99136078; called by muse, mutect2, varscan2
- FXR2 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 51/357 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV51468605; called by muse, mutect2, varscan2
- FZR1 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs762237038, COSV100281420, COSV58052018; called by muse, mutect2, varscan2
- GABRG2 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 71/255 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.396); catalogued as rs1445637165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAD1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs1271415571, COSV60152097; called by muse, mutect2
- GALNT12 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 89/417 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs776800914; called by muse, mutect2, varscan2
- GALNT5 | c.951C>A p.F317L | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1223716694; called by muse, mutect2, varscan2
- GALNT8 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 51/282 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52901465; called by muse, mutect2, varscan2
- GAS2L2 | c.2381G>A p.R794Q | Missense Mutation (SNP) | VAF 75/303 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs782603064; called by muse, mutect2, varscan2
- GBP6 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs756837037; called by muse, mutect2, varscan2
- GCNA | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 104/636 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.644); catalogued as rs767922902, COSV65466479; called by muse, varscan2
- GDF10 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 120/553 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1429920615; called by muse, mutect2, varscan2
- GDPD4 | c.517C>A p.L173I | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV60021619, COSV60023365; called by muse, mutect2, varscan2
- GFM1 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 50/334 reads (15%) | catalogued as rs1004779078, COSV51831614; called by muse, mutect2, varscan2
- GIGYF2 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 44/228 reads (19%) | catalogued as COSV65246402; called by muse, mutect2, varscan2
- GIMAP8 | c.1065C>A p.F355L | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as rs375143235; called by muse, mutect2, varscan2
- GJA3 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 69/335 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs781023239, COSV53834771; called by muse, mutect2, varscan2
- GLB1L3 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 65/337 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV101111108; called by muse, mutect2, varscan2
- GLOD4 | c.434G>A p.R145H (on ENST00000301328 / NM_001366247.1; = p.R130H on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56755300; called by muse, mutect2, varscan2
- GMPR2 | c.565C>T p.R189W (on ENST00000355299 / NM_001351022.2; = p.R207W on NM_016576.5) | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764422810; called by muse, mutect2, varscan2
- GNAI1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 81/404 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs1562844525; called by muse, mutect2, varscan2
- GNLY | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as rs149497301; called by muse, varscan2
- GOLGA6L7 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.23); catalogued as rs747558475, COSV101629691; called by muse, mutect2, varscan2
- GOLM1 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 52/316 reads (16%) | catalogued as COSV99974569; called by mutect2, varscan2
- GON4L | c.4362G>T p.K1454N | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs1364702370; called by muse, mutect2, varscan2
- GP2 | c.554C>A p.T185N (on ENST00000381362 / NM_001007240.3; = p.T182N on NM_001502.4) | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.597); catalogued as rs751840927; called by muse, mutect2, varscan2
- GPAT2 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.889); catalogued as rs747892123; called by mutect2, varscan2
- GPLD1 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.071); catalogued as rs778060726, COSV57753825; called by muse, mutect2, varscan2
- GPM6B | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.058); catalogued as rs1253105068; called by muse, mutect2, varscan2
- GPR101 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 67/313 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs137929096; called by muse, mutect2, varscan2
- GPR85 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs769982750, COSV104396774; called by muse, mutect2, varscan2
- GRAP2 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs769173032; called by muse, mutect2, varscan2
- GREB1 | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774958802; called by muse, mutect2, varscan2
- GREB1L | c.5695C>T p.R1899C | Missense Mutation (SNP) | VAF 72/320 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1346184582; called by muse, mutect2, varscan2
- GREM1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.069); catalogued as COSV55716147; called by muse, mutect2, varscan2
- GRIA2 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 67/268 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs777296512, COSV52391073; called by muse, mutect2, varscan2
- GRIK2 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.964); catalogued as COSV59720904; called by muse, varscan2
- GRIN1 | c.966G>A p.K322= | Splice Region (SNP) | VAF 30/159 reads (19%) | catalogued as COSV100160186, COSV59298718; called by muse, mutect2, varscan2
- GRK3 | c.970C>A p.L324I | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100151737; called by muse, mutect2, varscan2
- GSDMC | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs770331372, COSV52694670; called by muse, mutect2, varscan2
- GTF2H3 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV99967586, COSV99967689; called by muse, mutect2, varscan2
- GTF3C2 | c.2585G>A p.R862Q | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99273497; called by muse, mutect2, varscan2
- H2AZ2 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV56062414; called by muse, mutect2, varscan2
- H2BC14 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.595); catalogued as rs1474071318, COSV60797493, COSV60797855; called by muse, mutect2, varscan2
- H3-4 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 57/332 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV64210769; called by muse, mutect2, varscan2
- H6PD | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 82/390 reads (21%) | catalogued as COSV66230949, COSV66231775; called by muse, mutect2, varscan2
- HAO1 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs148598378; called by muse, mutect2, varscan2
- HAUS5 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs370335275; called by muse, mutect2, varscan2
- HAUS6 | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 26/203 reads (13%) | catalogued as rs765822489; called by muse, mutect2, varscan2
- HDAC5 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 53/345 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs138137922, COSV56822512; called by muse, mutect2, varscan2
- HEATR5A | c.5992T>G p.L1998V | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1375792882; called by muse, mutect2, varscan2
- HECTD1 | c.6475C>T p.L2159F | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV67949841; called by muse, mutect2, varscan2
- HELB | c.2575A>C p.N859H | Missense Mutation (SNP) | VAF 23/385 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV56074858; called by muse, mutect2
- HELQ | c.461A>C p.K154T | Missense Mutation (SNP) | VAF 57/275 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.107); catalogued as COSV99787296; called by muse, mutect2, varscan2
- HERC1 | c.9467C>T p.T3156M | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs769972685; called by muse, mutect2, varscan2
- HERPUD2 | c.496A>C p.N166H | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.288); catalogued as rs1169494796; called by muse, mutect2, varscan2
- HFM1 | c.2813G>A p.G938D | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99646979; called by muse, mutect2
- HIBCH | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 49/293 reads (17%) | catalogued as rs1328344821; called by muse, mutect2, varscan2
- HIP1 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs374190507; called by muse, mutect2, varscan2
- HMCN1 | c.340-1G>T p.X114_splice | Splice Site (SNP) | VAF 41/261 reads (16%) | catalogued as COSV99626252; called by muse, mutect2, varscan2
- HMCN1 | c.5876G>A p.R1959H | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs531145956; called by muse, varscan2
- HMGCR | c.2519G>A p.R840Q | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as rs755619444, COSV55315047; called by muse, mutect2, varscan2
- HMMR | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 56/261 reads (21%) | catalogued as COSV100701025, COSV100701055; called by mutect2, varscan2
- HNRNPAB | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 24/244 reads (10%) | catalogued as COSV57422826; called by muse, mutect2
- HNRNPCL1 | c.587C>A p.S196Y | Missense Mutation (SNP) | VAF 38/361 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs752818797, COSV58612395; called by mutect2, varscan2
- HNRNPU | c.2123G>A p.R708Q (on ENST00000283179; = p.R770Q on NM_004501.3) | Missense Mutation (SNP) | VAF 77/469 reads (16%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.979); catalogued as rs749543331; called by muse, mutect2, varscan2
- HORMAD2 | c.165G>T p.E55D | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100374260; called by muse, varscan2
- HOXB13 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV51706982; called by muse, mutect2, varscan2
- HPS5 | c.1640C>G p.S547C (on ENST00000349215 / NM_181507.2; = p.S433C on NM_007216.4) | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs780864594; called by muse, mutect2, varscan2
- HSP90AA1 | c.1311C>A p.F437L | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.224); catalogued as COSV99355500; called by muse, mutect2, varscan2
- HSPA8 | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 51/309 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99914699; called by muse, mutect2, varscan2
- HTR1A | c.779G>T p.S260I | Missense Mutation (SNP) | VAF 99/460 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV60501897; called by muse, mutect2, varscan2
- IDH3A | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1555429978, COSV51904904, COSV51907282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IDH3B | c.961A>G p.N321D | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs750603796; called by muse, varscan2
- IFNA10 | c.23T>G p.L8R | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV53331353; called by muse, mutect2, varscan2
- IFT140 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as rs758986711; called by muse, varscan2
- IGDCC4 | c.1693G>T p.E565* | Nonsense Mutation (SNP) | VAF 33/188 reads (18%) | catalogued as COSV100732870; called by mutect2, varscan2
- IGF2BP1 | c.1406G>T p.R469I | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV51731467, COSV51736758; called by muse, mutect2, varscan2
- IGF2R | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 32/130 reads (25%) | catalogued as COSV100806628; called by muse, mutect2, varscan2
- IGHV2-5 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs185589849; called by muse, mutect2, varscan2
- IGSF9B | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as rs753598938; called by muse, mutect2, varscan2
- IL10RB | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 43/290 reads (15%) | catalogued as rs771531217, COSV51614906; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1421948165, COSV56257020; called by mutect2, varscan2
- IL25 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV59307006; called by muse, mutect2, varscan2
- ILDR1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 81/417 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747963872, COSV56550154, COSV99878285; called by muse, mutect2, varscan2
- ILK | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 39/272 reads (14%) | catalogued as rs1179732298, COSV100196109; called by muse, mutect2, varscan2
- IMPDH1 | c.1525G>A p.E509K (on ENST00000470772 / NM_001142573.2; = p.E595K on NM_000883.4) | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.392); catalogued as rs748893918; called by muse, mutect2, varscan2
- IMPG2 | c.3568G>A p.V1190M | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs762391776, COSV51978313, COSV99516161; called by muse, mutect2, varscan2
- ING1 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 78/382 reads (20%) | catalogued as COSV58167150, COSV58169034; called by muse, mutect2, varscan2
- INHBE | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs147979089; called by muse, mutect2, varscan2
- INPP4B | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 92/456 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1405228238, COSV53717623; called by muse, mutect2, varscan2
- INTS1 | c.5141G>A p.R1714H | Missense Mutation (SNP) | VAF 74/361 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as rs370729536; called by muse, mutect2, varscan2
- IQCA1 | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1162225289; called by muse, mutect2, varscan2
- IRF3 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as rs771402454, COSV55862446, COSV99881402; called by muse, mutect2, varscan2
- IRX1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 75/383 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV57362412; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 41/243 reads (17%) | catalogued as COSV56439765; called by muse, mutect2, varscan2
- ITGA3 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 35/345 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs964967440; called by muse, mutect2
- ITGB2 | c.2179G>A p.A727T (on ENST00000302347; = p.A703T on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1045859276, COSV100186297; called by muse, mutect2, varscan2
- ITGB5 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776835945, COSV56146846, COSV56148331; called by muse, mutect2, varscan2
- ITGB5 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV56147739; called by muse, mutect2, varscan2
- ITPR3 | c.5914G>A p.A1972T | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs751533322, COSV65408685; called by muse, mutect2, varscan2
- JADE3 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 88/471 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.581); catalogued as rs782059228; called by muse, mutect2, varscan2
- JAG1 | c.3109G>A p.D1037N | Missense Mutation (SNP) | VAF 70/414 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as rs768823146, COSV54753981; called by muse, mutect2, varscan2
- JAK2 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 67/364 reads (18%) | catalogued as COSV67589468; called by muse, mutect2, varscan2
- JAK3 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as rs749143191, COSV71686087; called by muse, varscan2
- JAZF1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 68/317 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs748165340, COSV52244122; called by muse, mutect2, varscan2
- JCAD | c.1924G>A p.G642S | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100948590; called by muse, mutect2, varscan2
- KAT2B | c.2451G>T p.E817D | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs770108858; called by muse, mutect2, varscan2
- KAT5 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.069); catalogued as COSV57730422; called by muse, mutect2, varscan2
- KATNIP | c.2120C>T p.S707L | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs748274489, COSV55172870, COSV55187526; called by muse, mutect2, varscan2
- KCNA5 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 87/370 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.394); catalogued as rs150208806, COSV52906300; called by muse, mutect2, varscan2
- KCND1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 83/417 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as rs782341099; called by muse, mutect2, varscan2
- KCNH4 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs867014968; called by muse, mutect2, varscan2
- KCNH7 | c.3470G>A p.R1157Q | Missense Mutation (SNP) | VAF 88/433 reads (20%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs374095828, COSV59795271; called by muse, mutect2, varscan2
- KCNJ10 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100927972; called by mutect2, varscan2
- KCNJ14 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs745540997, COSV60737739; called by muse, mutect2, varscan2
- KCNN2 | c.875A>T p.N292I (on ENST00000264773; = p.N504I on NM_021614.4) | Missense Mutation (SNP) | VAF 53/297 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53295386; called by muse, mutect2, varscan2
- KCNS1 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as rs552804693, COSV60260529; called by muse, mutect2, varscan2
- KCNU1 | c.637C>A p.L213I | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67753311; called by muse, mutect2, varscan2
- KCNU1 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs754818690; called by muse, mutect2, varscan2
- KDM3B | c.4483C>T p.R1495* | Nonsense Mutation (SNP) | VAF 33/176 reads (19%) | catalogued as COSV58690312; called by muse, mutect2, varscan2
- KDM5A | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 59/410 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV66990391; called by muse, mutect2, varscan2
- KDR | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs539911006, COSV55758376, COSV99819088; ClinVar: not provided; called by muse, mutect2, varscan2
- KHDRBS1 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV56981893; called by muse, mutect2, varscan2
- KIAA1217 | c.4768C>T p.R1590C | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs373521321; called by muse, mutect2, varscan2
- KIAA1614 | c.3181C>T p.R1061W | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs371574880; called by muse, mutect2, varscan2
- KIAA1958 | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 74/384 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as rs370233153; called by muse, mutect2
- KIAA2026 | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 71/335 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67353145; called by muse, mutect2, varscan2
- KIF14 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 62/413 reads (15%) | catalogued as rs775644664; called by muse, mutect2, varscan2
- KIF17 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 63/361 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as rs762645455, COSV56122474; called by muse, mutect2, varscan2
- KIF1A | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.218); catalogued as rs1049441176, COSV57498002; called by muse, mutect2, varscan2
- KIF20B | c.2302G>T p.E768* (on ENST00000371728 / NM_001284259.2; = p.E728* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 13/132 reads (10%) | catalogued as COSV53302149; called by muse, mutect2, varscan2
- KIF20B | c.2880G>T p.K960N (on ENST00000371728 / NM_001284259.2; = p.K920N on NM_016195.4) | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV53310715; called by muse, mutect2, varscan2
- KIF20B | c.3128G>A p.R1043Q (on ENST00000371728 / NM_001284259.2; = p.R1003Q on NM_016195.4) | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs371655633, COSV53306679; called by muse, mutect2, varscan2
- KIF21B | c.3394G>A p.D1132N | Missense Mutation (SNP) | VAF 43/312 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs992008787; called by muse, mutect2, varscan2
- KIF3A | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 82/415 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.77); catalogued as rs1171722465, COSV66413297; called by muse, mutect2, varscan2
- KIF3C | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV53099869; called by muse, mutect2, varscan2
- KIRREL1 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 69/391 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs761586318; called by muse, mutect2, varscan2
- KIZ | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55684118, COSV99852402; called by muse, mutect2, varscan2
- KLF11 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 52/390 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100007866; called by muse, mutect2, varscan2
- KLHL10 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.098); catalogued as rs1204134487, COSV99509579; called by muse, mutect2, varscan2
- KLHL11 | c.1474C>T p.R492* | Nonsense Mutation (SNP) | VAF 31/187 reads (17%) | catalogued as rs782630323; called by muse, mutect2, varscan2
- KLHL6 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.021); catalogued as rs749942087, COSV58067504; called by muse, mutect2, varscan2
- KLK6 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1195056349, COSV59565347, COSV59566849; called by muse, mutect2, varscan2
- KMO | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); catalogued as COSV63810891; called by muse, mutect2, varscan2
- KMT2A | c.2161C>T p.R721* | Nonsense Mutation (SNP) | VAF 42/254 reads (17%) | catalogued as COSV63285150; called by muse, mutect2, varscan2
- KMT2B | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs202218975, COSV99385946; called by muse, varscan2
- KMT2C | c.11983C>T p.R3995* | Nonsense Mutation (SNP) | VAF 34/195 reads (17%) | catalogued as rs1005725533, COSV51501908; called by muse, mutect2, varscan2
- KMT2C | c.2507C>A p.S836Y | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100068619, COSV51277608; called by muse, mutect2, varscan2
- KMT2D | c.10057C>A p.Q3353K | Missense Mutation (SNP) | VAF 53/312 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99985604; called by muse, mutect2, varscan2
- KNL1 | c.2993G>A p.R998K (on ENST00000346991 / NM_170589.5; = p.R972K on NM_144508.5) | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1314890959, COSV61153072; called by muse, mutect2, varscan2
- KNL1 | c.6817G>A p.A2273T (on ENST00000346991 / NM_170589.5; = p.A2247T on NM_144508.5) | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.938); catalogued as rs761149870, COSV61154176; called by muse, mutect2, varscan2
- KPNA1 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 103/411 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60271089; called by muse, mutect2, varscan2
- KRT79 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 71/373 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs765976515, COSV57939885; called by muse, mutect2, varscan2
- KRTAP10-5 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 97/596 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs372733073; called by muse, mutect2, varscan2
- KSR2 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 92/405 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60367931; called by muse, mutect2, varscan2
- L1TD1 | c.393A>C p.E131D | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); catalogued as rs1182086811, COSV63133754; called by muse, mutect2, varscan2
- L3MBTL2 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 36/220 reads (16%) | catalogued as COSV99345856; called by muse, mutect2, varscan2
- LAMA2 | c.2323-1G>T p.X775_splice | Splice Site (SNP) | VAF 32/140 reads (23%) | catalogued as rs1278823424; called by muse, mutect2, varscan2
- LAMB2 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 68/271 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs924410863; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAX1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV100920038, COSV104425678; called by muse, mutect2
- LBP | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.246); catalogued as rs766790395; called by muse, mutect2, varscan2
- LCE2B | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 92/411 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV64227685; called by mutect2, varscan2
- LDB2 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.194); catalogued as rs1360152835, COSV100452617; called by muse, mutect2, varscan2
- LEMD3 | c.1975G>T p.E659* | Nonsense Mutation (SNP) | VAF 59/375 reads (16%) | catalogued as COSV104413092; called by muse, mutect2, varscan2
- LGR4 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 44/221 reads (20%) | catalogued as COSV101004305, COSV99061577; called by mutect2, varscan2
- LHX6 | c.239G>A p.R80Q (on ENST00000373755 / NM_001242334.2; = p.R109Q on NM_014368.5) | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs866784597; called by muse, mutect2, varscan2
- LIFR | c.2936C>T p.S979L | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1197291750, COSV99664749; called by muse, mutect2, varscan2
- LIFR | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs373421600; called by muse, mutect2, varscan2
- LIFR | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 60/423 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99665368; called by muse, mutect2, varscan2
- LILRA1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 85/343 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs534531456, COSV99252184; called by muse, mutect2, varscan2
- LILRB1 | c.1908C>A p.F636L (on ENST00000427581; = p.F585L on NM_006669.6) | Missense Mutation (SNP) | VAF 77/544 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.185); catalogued as COSV61117119; called by muse, mutect2, varscan2
- LIPE | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs756437778, COSV54921047; called by muse, mutect2, varscan2
- LIX1 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.052); catalogued as rs1222062561; called by muse, mutect2, varscan2
- LMO7 | c.845G>A p.R282Q (on ENST00000357063; = p.R297Q on NM_005358.5) | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765556451; called by muse, mutect2, varscan2
- LNPEP | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 56/322 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs1467432611; called by muse, mutect2, varscan2
- LPAR4 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 78/459 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs867126614; called by muse, mutect2, varscan2
- LRIG3 | c.1983C>A p.F661L | Missense Mutation (SNP) | VAF 72/399 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV57868981; called by muse, mutect2, varscan2
- LRPPRC | c.3077C>T p.S1026L | Missense Mutation (SNP) | VAF 52/295 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1464347923; called by muse, mutect2, varscan2
- LRRC23 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.039); catalogued as rs782155428, COSV50387286, COSV50395581; called by muse, mutect2, varscan2
- LRRC23 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782748706, COSV50386825; called by muse, mutect2, varscan2
- LRRC49 | c.1167A>G p.T389= | Splice Region (SNP) | VAF 25/154 reads (16%) | catalogued as rs749589585; called by muse, mutect2, varscan2
- LRRC63 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as rs556213982; called by muse, varscan2
- LRRC63 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1341558582, COSV66512242; called by muse, varscan2
- LRRC63 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 101/416 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs1300658469; called by muse, varscan2
- LRRN1 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 73/324 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs947264741, COSV60012870; called by muse, mutect2, varscan2
- LTBP3 | c.2569C>T p.R857W | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as rs368156902; called by muse, mutect2, varscan2
- LTF | c.1861C>T p.R621W | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759996198; called by muse, mutect2, varscan2
- LY6K | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 83/319 reads (26%) | catalogued as COSV52833392; called by muse, mutect2, varscan2
- LY96 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142571384; called by muse, mutect2, varscan2
- LYST | c.1115A>C p.D372A | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs906448234; called by muse, mutect2, varscan2
- MAB21L2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as rs749605702; called by muse, mutect2, varscan2
- MACO1 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.382); catalogued as rs569288167; called by muse, mutect2, varscan2
- MAGEA1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs1216226226, COSV63118513; called by muse, mutect2, varscan2
- MAGEB10 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 60/336 reads (18%) | catalogued as COSV63311150; called by muse, mutect2, varscan2
- MAGEC3 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 95/393 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.705); catalogued as rs772070241, COSV100025227, COSV68924260; called by muse, mutect2, varscan2
- MAK16 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs531979967; called by muse, mutect2, varscan2
- MAP10 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 54/477 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs768784310, COSV69364762; called by muse, mutect2, varscan2
- MAP1B | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57096936; called by muse, mutect2, varscan2
- MAP1B | c.5272G>T p.D1758Y | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs1370044802, COSV57106464; called by muse, mutect2, varscan2
- MAP3K1 | c.4027G>T p.E1343* | Nonsense Mutation (SNP) | VAF 22/316 reads (7%) | catalogued as COSV68122689, COSV68127321; called by muse, mutect2
- MAP3K7 | c.1430G>A p.R477Q (on ENST00000369329 / NM_145331.3; = p.R450Q on NM_003188.4) | Missense Mutation (SNP) | VAF 60/345 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as rs183005565; called by muse, mutect2, varscan2
- MAP7 | c.626C>A p.S209Y | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63419385; called by muse, mutect2, varscan2
- MAPK1IP1L | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated, low confidence (0.51); PolyPhen probably damaging (0.979); catalogued as rs1039840270; called by muse, mutect2, varscan2
- MBOAT2 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 67/376 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471364240, COSV60007642; called by muse, mutect2, varscan2
- MCAT | c.766C>A p.H256N | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as rs1282620461; called by muse, mutect2, varscan2
- MCM2 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372340490; called by muse, mutect2, varscan2
- MDH1 | c.924C>A p.F308L | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51862842; called by muse, mutect2, varscan2
- MED12 | c.533G>T p.R178I | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV61332497; called by muse, mutect2, varscan2
- MED14 | c.2477C>T p.S826L | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.945); catalogued as rs1464575337, COSV61356493; called by muse, mutect2, varscan2
- MED17 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 44/292 reads (15%) | catalogued as rs200969521; called by muse, varscan2
- MEFV | c.1198C>A p.L400M | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.199); catalogued as rs777194815; called by muse, mutect2, varscan2
- MEGF10 | c.3167G>A p.R1056Q | Missense Mutation (SNP) | VAF 71/323 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as rs1453250767, COSV57250130; called by muse, mutect2, varscan2
- MEPE | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs868133447, COSV63072516; called by muse, mutect2, varscan2
- METTL21A | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1336954438, COSV55881351; called by muse, mutect2, varscan2
- METTL6 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV67542406; called by muse, mutect2, varscan2
- MFSD4A | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 62/468 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1227992514, COSV100901689; called by muse, mutect2, varscan2
- MFSD5 | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 51/237 reads (22%) | catalogued as rs767465967, COSV100289055, COSV61565493; called by muse, mutect2, varscan2
- MFSD8 | c.1399C>A p.L467I | Missense Mutation (SNP) | VAF 67/334 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs754100928; called by muse, mutect2, varscan2
- MGA | c.2669C>A p.S890Y | Missense Mutation (SNP) | VAF 65/347 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1363709175; called by muse, mutect2, varscan2
- MGAM2 | c.5051G>A p.R1684Q | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs752457422, COSV101522967; called by muse, varscan2
- MIER3 | c.110G>T p.R37I | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV104396431, COSV61230105; called by muse, mutect2, varscan2
- MIGA1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 48/269 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.125); catalogued as rs760651456, COSV66223581; called by muse, mutect2, varscan2
- MIPOL1 | c.456G>T p.E152D | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV59379160; called by muse, mutect2, varscan2
- MLNR | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 111/344 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs201886143; called by muse, mutect2, varscan2
- MMP27 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 50/306 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs777472661, COSV52782154; called by muse, mutect2, varscan2
- MOK | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV51963785; called by muse, mutect2
- MPPE1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs780355922, COSV57882119, COSV57882130; called by mutect2, varscan2
- MRC2 | c.519C>T p.H173= | Splice Region (SNP) | VAF 27/172 reads (16%) | catalogued as rs140481613; called by muse, mutect2, varscan2
- MRGPRD | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.753); catalogued as rs1240062317; called by muse, mutect2, varscan2
- MROH6 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 87/476 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV52786031; called by muse, mutect2, varscan2
- MRPL1 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 59/319 reads (18%) | catalogued as COSV59674633; called by muse, mutect2, varscan2
- MRPL39 | c.749G>T p.R250I | Missense Mutation (SNP) | VAF 53/311 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV56260790; called by muse, mutect2, varscan2
- MSH6 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as rs63750258, CM015392, COSV99029714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSL2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 65/313 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.058); catalogued as COSV53862480; called by muse, mutect2, varscan2
- MSN | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 40/281 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.655); catalogued as COSV64303362; called by muse, mutect2, varscan2
- MTHFD2L | c.206G>A p.R69Q (on ENST00000395759 / NM_001144978.2; = p.R11Q on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs765921680, COSV57466788; called by muse, varscan2
- MTMR14 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 51/327 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs762474515, COSV56004522; called by muse, mutect2, varscan2
- MTMR6 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.243); catalogued as COSV67808906; called by muse, varscan2
- MTMR8 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 80/439 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100878284, COSV66396488; called by muse, mutect2, varscan2
- MTOR | c.6454C>T p.R2152C | Missense Mutation (SNP) | VAF 63/340 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs752458445, COSV63869241; called by muse, mutect2, varscan2
- MTUS2 | c.3640G>A p.E1214K (on ENST00000612955 / NM_001366650.1; = p.E193K on NM_015233.6) | Missense Mutation (SNP) | VAF 98/394 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775222983, COSV66420118, COSV66421290; called by muse, mutect2, varscan2
- MUC16 | c.7830G>T p.K2610N | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV67480436, COSV67490856; called by muse, mutect2, varscan2
- MUC2 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 70/394 reads (18%) | SIFT tolerated (0.14); catalogued as rs267602687; called by muse, mutect2, varscan2
- MYCBP2 | c.3077G>A p.R1026Q (on ENST00000357337; = p.R1064Q on NM_015057.5) | Missense Mutation (SNP) | VAF 73/367 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs766468180, COSV62015008; called by muse, mutect2, varscan2
- MYH6 | c.1861C>A p.L621I | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); catalogued as COSV62453315; called by muse, mutect2, varscan2
- MYH7 | c.3152C>T p.A1051V | Missense Mutation (SNP) | VAF 66/308 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs727504358, CM122817; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO5C | c.4138C>A p.L1380I | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.271); catalogued as COSV55909373; called by muse, mutect2, varscan2
- MYO9A | c.3650G>A p.R1217Q | Missense Mutation (SNP) | VAF 57/357 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs193029114; called by muse, mutect2, varscan2
- MYO9A | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61847500; called by muse, varscan2
- MYOM3 | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV58389734; called by muse, mutect2, varscan2
- MYPN | c.3767C>T p.S1256L | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs542627169, COSV100589365, COSV100590591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAA15 | c.1966G>T p.E656* | Nonsense Mutation (SNP) | VAF 36/266 reads (14%) | catalogued as COSV56717496, COSV56721994; called by muse, mutect2, varscan2
- NAA25 | c.2764G>T p.E922* | Nonsense Mutation (SNP) | VAF 28/176 reads (16%) | catalogued as COSV55702512; called by mutect2, varscan2
- NAA35 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 82/443 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64484266; called by muse, mutect2, varscan2
- NACA2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 66/380 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as rs1298768878, COSV101478554, COSV71713152; called by muse, mutect2, varscan2
- NADSYN1 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.389); catalogued as rs765490391; called by muse, mutect2, varscan2
- NALCN | c.3393C>A p.I1131= | Splice Region (SNP) | VAF 32/203 reads (16%) | catalogued as COSV51961509; called by muse, mutect2, varscan2
- NAPEPLD | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 83/381 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs746125875, COSV58522804; called by muse, mutect2, varscan2
- NAPRT | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 67/304 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as rs746163132; called by muse, mutect2, varscan2
- NAPSA | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs898399448, COSV53796589; called by muse, mutect2, varscan2
- NASP | c.459A>C p.E153D | Missense Mutation (SNP) | VAF 44/356 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs565146317; called by muse, mutect2, varscan2
- NASP | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs199692248, COSV59645739; called by muse, mutect2, varscan2
- NBPF9 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 86/516 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as rs782190347, COSV56018403; called by muse, varscan2
- NCBP2 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 57/281 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV58318484; called by muse, mutect2, varscan2
- NCKAP5 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 71/255 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1264931730, COSV58447039; called by muse, mutect2, varscan2
- NCOA6 | c.4901C>T p.A1634V | Missense Mutation (SNP) | VAF 79/342 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs146019486; called by muse, mutect2, varscan2
- NCOR2 | c.4414G>A p.D1472N | Missense Mutation (SNP) | VAF 83/355 reads (23%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.996); catalogued as rs374057697; called by muse, mutect2, varscan2
- NDUFS2 | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs932640288, COSV57154508; called by muse, mutect2, varscan2
- NEB | c.14840C>T p.S4947L | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs780754459, COSV51269633; called by muse, mutect2, varscan2
- NECTIN4 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV63512811; called by muse, mutect2, varscan2
- NEFL | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 93/362 reads (26%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.953); catalogued as COSV55336970; called by muse, mutect2, varscan2
- NES | c.2369C>A p.S790Y | Missense Mutation (SNP) | VAF 55/413 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100957795; called by muse, mutect2, varscan2
- NEUROD1 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 61/370 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs925185201; called by muse, mutect2, varscan2
- NEUROD4 | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 50/324 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54471402, COSV54474137; called by muse, mutect2, varscan2
- NF2 | c.288C>A p.F96L | Missense Mutation (SNP) | VAF 48/301 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.347); catalogued as CD941738, COSV58532568; called by muse, mutect2, varscan2
- NFRKB | c.1750C>T p.R584W (on ENST00000446488 / NM_001143835.2; = p.R609W on NM_006165.3) | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1216386086, COSV58757330; called by muse, mutect2, varscan2
- NFXL1 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 86/384 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs372423597, COSV100217042, COSV61198477; called by muse, mutect2, varscan2
- NHLRC2 | c.1116C>A p.D372E | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65174427; called by muse, mutect2, varscan2
- NIBAN1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs542303174, COSV62287892; called by muse, mutect2, varscan2
- NISCH | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1559621170; called by muse, mutect2, varscan2
- NISCH | c.4308C>A p.D1436E | Missense Mutation (SNP) | VAF 68/326 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV58741775; called by muse, varscan2
- NKAIN3 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV60687120; called by muse, varscan2
- NKAP | c.611G>T p.R204I | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV65056037; called by mutect2, varscan2
- NLGN1 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 61/299 reads (20%) | catalogued as rs1246921076, COSV64341360; called by muse, mutect2, varscan2
- NLRC5 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs1450559334, COSV52649650, COSV52661049; called by muse, mutect2, varscan2
- NLRP5 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 49/267 reads (18%) | catalogued as rs1272041921, COSV66766107; called by muse, mutect2, varscan2
- NLRP5 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs939295010, COSV66761960, COSV66762753; called by muse, mutect2, varscan2
- NOC3L | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993295; called by muse, mutect2, varscan2
- NOL10 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 46/296 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs1347809627; called by muse, mutect2, varscan2
- NOTCH2 | c.5218C>A p.L1740I | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs747138507, COSV56706304, COSV56709796; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPAS3 | c.558A>T p.Q186H (on ENST00000356141 / NM_001164749.2; = p.Q154H on NM_022123.3) | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100389799; called by muse, mutect2, varscan2
- NPAS4 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.204); catalogued as rs771020229; called by muse, mutect2, varscan2
2,517 further variants in this file (1,667 protein-altering or splice-affecting, 713 silent, 137 other) are not listed here.
